Somatic mutation profile of tumor specimen TCGA-A4-A5Y0-01A (aliquot TCGA-A4-A5Y0-01A-11D-A31X-10) from TCGA case TCGA-A4-A5Y0, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.2 years (22,341 days).
Specimen TCGA-A4-A5Y0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1864bee3-b3b7-4e59-b25d-9ecc63a0d14f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-A5Y0-11A (Solid Tissue Normal), aliquot TCGA-A4-A5Y0-11A-11D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96d833aa-c902-40a6-a3da-c4b2d6347d60

The open-access MAF lists 62 somatic variants for this specimen: 53 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Frame Shift Del 9, Silent 8, Splice Site 2, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A4GNT | c.408+2T>G p.X136_splice | Splice Site (SNP) | VAF 91/186 reads (49%) | catalogued as COSV52629743; called by muse, mutect2, varscan2
- ACTL6A | c.919G>T p.G307* | Nonsense Mutation (SNP) | VAF 142/280 reads (51%) | catalogued as COSV66999296; called by mutect2, varscan2
- ADAMTS12 | c.4601G>T p.S1534I | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV61273116; called by muse, mutect2, varscan2
- ANKRD12 | c.4438C>G p.Q1480E | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV50838595; called by muse, mutect2, varscan2
- ASCC3 | c.4415G>T p.R1472L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64978721; called by muse, mutect2, varscan2
- ATP11C | c.1983G>C p.E661D | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.086); catalogued as COSV59563394, COSV59570244; called by muse, mutect2, varscan2
- BAZ2A | c.1039A>T p.N347Y | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV51641190; called by muse, mutect2, varscan2
- BRD2 | c.1200+1G>A p.X400_splice | Splice Site (SNP) | VAF 20/41 reads (49%) | catalogued as COSV100875784, COSV66374312; called by muse, mutect2
- CCR7 | c.825C>A p.F275L | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.115); catalogued as COSV55850201; called by muse, mutect2, varscan2
- CISH | c.144G>T p.E48D (on ENST00000348721 / NM_145071.4; = p.E65D on NM_013324.6) | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs768686842, COSV62295289; called by muse, mutect2, varscan2
- CTNNA2 | c.1049T>C p.M350T | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.565); catalogued as COSV63589660; called by muse, mutect2, varscan2
- CUL3 | c.1637G>C p.R546P | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52368373, COSV52371739; called by muse, mutect2, varscan2
- DCTPP1 | c.484T>A p.C162S | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV60000790; called by muse, mutect2, varscan2
- DHX38 | c.3358C>T p.H1120Y | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51699971; called by muse, mutect2, varscan2
- DNAH1 | c.1716C>A p.S572R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV70233634; called by muse, mutect2, varscan2
- E2F3 | c.1188C>G p.N396K | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV60899128; called by muse, mutect2, varscan2
- EDN3 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV61109378; called by muse, mutect2, varscan2
- EME2 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as rs754262901, COSV51602279; called by muse, mutect2, varscan2
- FBXO46 | c.907A>G p.K303E | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.083); catalogued as COSV58349424; called by muse, mutect2, varscan2
- FOXA1 | c.1201T>A p.S401T | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51648397; called by muse, mutect2, varscan2
- HHIPL2 | c.1637G>A p.C546Y | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58566774; called by muse, mutect2, varscan2
- HLA-A | c.94T>G p.F32V | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65143870; called by muse, mutect2
- KCNH6 | c.1187A>G p.Y396C | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV59006475; called by muse, mutect2, varscan2
- KLB | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 70/172 reads (41%) | catalogued as COSV57303863; called by muse, mutect2, varscan2
- MDN1 | c.11980A>C p.K3994Q | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV65527640; called by muse, mutect2, varscan2
- MOK | c.290G>T p.R97I | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV51966835; called by muse, mutect2, varscan2
- NCMAP | c.13A>T p.T5S | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.269); catalogued as COSV65557325; called by muse, varscan2
- NRCAM | c.3379A>G p.M1127V | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV61045091; called by muse, mutect2, varscan2
- OR6V1 | c.810G>C p.K270N | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV69237567; called by muse, mutect2, varscan2
- OVGP1 | c.1183T>G p.F395V | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV63859615; called by muse, mutect2, varscan2
- PPP1R9B | c.2057A>G p.Q686R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV57542152; called by muse, mutect2, varscan2
- RABGGTB | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs749246034, COSV60638549; called by muse, mutect2, varscan2
- RASEF | c.637A>C p.I213L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.2); catalogued as COSV64588180; called by muse, varscan2
- RFX3 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.774); catalogued as COSV56522336; called by muse, mutect2, varscan2
- RIOX1 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.758); catalogued as COSV58374487; called by muse, mutect2, varscan2
- SF3B2 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV59429600; called by muse, mutect2
- SNAI2 | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50079023, COSV50079906; called by muse, mutect2, varscan2
- STUM | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.02); catalogued as rs531129279, COSV64684976; called by muse, mutect2, varscan2
- TMTC2 | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1477099251, COSV58262649, COSV58264453; called by muse, mutect2, varscan2
- VPS26B | c.38A>T p.E13V | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.432); catalogued as COSV55546025; called by muse, varscan2
- WDFY3 | c.2786G>T p.R929L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55710210; called by muse, mutect2, varscan2
- WDR75 | c.51G>C p.L17F | Missense Mutation (SNP) | VAF 70/366 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs201125667, COSV59106551; called by muse, varscan2
- WNT10B | c.359C>A p.S120Y | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1403899627, COSV56406089; called by muse, mutect2, varscan2
- ZNF43 | c.2143T>A p.F715I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61685231; called by muse, mutect2, varscan2
- ADCY9 | c.2047del p.E683Rfs*23 | Frame Shift Del (DEL) | VAF 32/79 reads (41%) | called by mutect2, pindel, varscan2
- CD83 | c.449del p.A150Vfs*7 | Frame Shift Del (DEL) | VAF 45/115 reads (39%) | called by mutect2, pindel, varscan2
- EXOSC2 | c.875del p.E292Gfs*57 | Frame Shift Del (DEL) | VAF 39/96 reads (41%) | called by mutect2, pindel, varscan2
- KANK4 | c.418_419delinsA p.L140Rfs*21 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by pindel, varscan2*
- KNL1 | c.1975del p.S659Afs*2 (on ENST00000346991 / NM_170589.5; = p.S633Afs*2 on NM_144508.5) | Frame Shift Del (DEL) | VAF 40/117 reads (34%) | called by mutect2, pindel, varscan2
- MTSS1 | c.1051del p.S351Lfs*73 | Frame Shift Del (DEL) | VAF 22/46 reads (48%) | called by mutect2, varscan2
- MYH13 | c.4367del p.V1456Afs*33 | Frame Shift Del (DEL) | VAF 27/94 reads (29%) | called by mutect2, pindel, varscan2
- PRKCI | c.1782del p.E594Dfs*18 | Frame Shift Del (DEL) | VAF 31/86 reads (36%) | called by mutect2, pindel, varscan2
- ULK4 | c.2209del p.I737Lfs*24 | Frame Shift Del (DEL) | VAF 50/112 reads (45%) | called by mutect2, varscan2
- BSN | c.8577C>T p.T2859= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs149034379; called by muse, mutect2, varscan2
- CCT3 | c.327T>C p.A109= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV55290673; called by muse, mutect2, varscan2
- H6PD | c.543C>T p.F181= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs375431974, COSV66231876; called by muse, mutect2, varscan2
- KIF2B | c.1254C>T p.V418= | Silent (SNP) | VAF 64/207 reads (31%) | catalogued as COSV52133919; called by muse, mutect2, varscan2
- LAMA1 | c.5059C>T p.L1687= | Silent (SNP) | VAF 65/129 reads (50%) | catalogued as rs1216836136, COSV67541748; called by muse, mutect2, varscan2
- MBP | c.705G>A p.P235= (on ENST00000355994 / NM_001025101.2; = p.P128= on NM_002385.3) | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs112511603, COSV62830097; called by muse, mutect2, varscan2
- NCOR1 | c.4518A>C p.T1506= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV51988525; called by muse, mutect2, varscan2
- SLC4A1 | c.957A>T p.L319= | Silent (SNP) | VAF 51/174 reads (29%) | catalogued as COSV52262090, COSV52262343; called by muse, mutect2, varscan2
- PAK6 | c.-117-459C>T | Intron (SNP) | VAF 51/120 reads (43%) | catalogued as COSV53047192; called by muse, mutect2, varscan2
